TARGET case TARGET-10-PAUXZX — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bf5cb2a4-610c-5a2c-b440-6d441007c6df

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 5 years.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 5.0 years (1,828 days); Year of diagnosis: 2012.
   Treatment given: Protocol identifier: AALL1131.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Positive.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 322 ×10³/µL.
- Day 8: Minimal Residual Disease (Flow Cytometry) 1.4%.
- Day 29: Bone Marrow blast count 0%; Minimal Residual Disease (Flow Cytometry) 0.06%.

Biospecimens (5 samples)
- Sample TARGET-10-PAUXZX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PAUXZX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Samples TARGET-10-PAUXZX-60.1C, TARGET-10-PAUXZX-60.2C, TARGET-10-PAUXZX-60.3C (3 with the same recorded description): Sample type: Primary Xenograft Tissue; Tissue type: Tumor; Tumor descriptor: Xenograft.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Xenografts_20230727.xlsx:
- WBC at Diagnosis: 322.2
- CNS Status at Diagnosis: CNS 1
- MRD Day 8: 1.4
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0.06
- MRD Day 29 Sensitivity: 0.01
- ETV6 RUNX1 Fusion Status: Positive
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 29: 0
- Karyotype: 46,XX,t(9;12)(q34;p13)[18]/46,XX[2]
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: B Cell ALL
